Somatic mutation profile of tumor specimen TCGA-CN-A6V1-01A (aliquot TCGA-CN-A6V1-01A-12D-A34J-08) from TCGA case TCGA-CN-A6V1, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: GX; Age at diagnosis: 59.5 years (21,730 days).
Specimen TCGA-CN-A6V1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd75c485-c0f2-45f9-a150-ce54a97621d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-A6V1-10B (Blood Derived Normal), aliquot TCGA-CN-A6V1-10B-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/069fdb7f-81f4-42be-94c6-d0656ad94ce5

The open-access MAF lists 273 somatic variants for this specimen: 184 protein-altering or splice-affecting, 86 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 162, Silent 86, Nonsense Mutation 14, Splice Site 3, Splice Region 2, Frame Shift Ins 1, Intron 1, Frame Shift Del 1, 5'Flank 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC9 | c.715C>T p.H239Y | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.109); catalogued as COSV99685963; called by muse, mutect2
- AC139530.2 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV100381731; called by muse, mutect2
- ADGRA1 | c.1260G>A p.L420= | Splice Region (SNP) | VAF 4/32 reads (13%) | catalogued as COSV63416805; called by muse, mutect2
- ADGRA2 | c.1402C>T p.Q468* | Nonsense Mutation (SNP) | VAF 5/84 reads (6%) | catalogued as COSV100178079; called by muse, mutect2
- ADGRB2 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as rs781471521, COSV57076022; called by mutect2, varscan2
- ADGRL3 | c.904C>T p.R302W (on ENST00000506720 / NM_001322402.2; = p.R234W on NM_015236.6) | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs548241584, COSV72272902; called by mutect2, varscan2
- ADM | c.249-1G>A p.X83_splice | Splice Site (SNP) | VAF 6/46 reads (13%) | catalogued as COSV99534264; called by mutect2, varscan2
- AKAP9 | c.5542G>C p.E1848Q (on ENST00000359028; = p.E1816Q on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100662534, COSV100663305; called by muse, mutect2
- AMBRA1 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100094287; called by muse, mutect2
- ANKEF1 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV101001034; called by muse, mutect2
- APOA4 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.328); catalogued as COSV100759341; called by muse, mutect2
- ARHGAP12 | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.017); catalogued as COSV100260643; called by muse, mutect2
- ARHGAP18 | c.1202G>A p.S401N | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.937); catalogued as COSV100936244; called by muse, mutect2
- ARHGEF28 | c.1000G>T p.E334* | Nonsense Mutation (SNP) | VAF 12/170 reads (7%) | catalogued as COSV99709309; called by muse, mutect2
- ARID1A | c.1582C>T p.Q528* | Nonsense Mutation (SNP) | VAF 17/303 reads (6%) | catalogued as COSV61377237; called by muse, mutect2
- ARMC7 | c.139C>A p.P47T | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1490688902, COSV99822664; called by muse, mutect2
- ATAD2B | c.3941C>T p.S1314L | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV99477850; called by muse, mutect2
- ATM | c.8962G>A p.D2988N | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1158699807, COSV99590084; called by muse, mutect2
- ATR | c.4582C>T p.L1528F | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV63385391, COSV63385889, COSV63388234; called by muse, mutect2
- BMPR2 | c.820G>C p.E274Q | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV101001543; called by muse, mutect2
- BRAP | c.657G>A p.M219I | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV100554179; called by muse, mutect2
- BZW1 | c.220C>G p.L74V | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV100729864; called by muse, mutect2
- C18orf54 | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1203031594, COSV100266568; called by muse, mutect2
- C1orf162 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as COSV100636222; called by muse, mutect2
- CAPN2 | c.1237C>G p.Q413E | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV54335364, COSV54339385; called by muse, mutect2
- CAVIN2 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.12); catalogued as COSV58426016; called by muse, mutect2
- CCDC54 | c.686C>A p.S229* | Nonsense Mutation (SNP) | VAF 11/163 reads (7%) | catalogued as COSV99660231; called by muse, mutect2
- CDH16 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV100233929; called by muse, mutect2, varscan2
- CHUK | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV100957158; called by muse, mutect2
- CLIC1 | c.362C>T p.S121L | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV101007512; called by muse, mutect2
- CNNM3 | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.359); catalogued as COSV100562666, COSV100562711; called by muse, mutect2
- CNTN2 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as COSV100085137; called by muse, mutect2
- CNTN3 | c.1222C>T p.P408S | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV99724849; called by muse, mutect2
- COMTD1 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.157); catalogued as COSV53685317; called by muse, mutect2, varscan2
- CPAMD8 | c.2749G>C p.E917Q (on ENST00000651564; = p.E870Q on NM_015692.5) | Missense Mutation (SNP) | VAF 9/261 reads (3%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.543); catalogued as COSV101488527; called by muse, mutect2
- CSRNP2 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV57334233; called by muse, mutect2
- CUL1 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV100296716; called by muse, varscan2
- CYP2C18 | c.366G>C p.E122D | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV53670927; called by muse, mutect2, varscan2
- DAXX | c.2012C>T p.S671F | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.947); catalogued as COSV99802255; called by muse, mutect2
- DCLK1 | c.1666C>G p.P556A | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99711707; called by muse, mutect2
- DCLK1 | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1376151056, COSV55204542; called by muse, mutect2
- DHX9 | c.1507C>T p.R503* | Nonsense Mutation (SNP) | VAF 7/187 reads (4%) | catalogued as COSV62360398; called by muse, mutect2
- DHX9 | c.3533C>G p.S1178C | Missense Mutation (SNP) | VAF 8/161 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as COSV62360225; called by muse, mutect2
- DIXDC1 | c.1780C>G p.P594A (on ENST00000440460 / NM_001037954.4; = p.P383A on NM_033425.4) | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as COSV100180287; called by muse, mutect2
- DMGDH | c.138G>A p.W46* | Nonsense Mutation (SNP) | VAF 7/157 reads (4%) | catalogued as COSV99669136; called by muse, mutect2
- DMXL2 | c.3719C>G p.S1240C | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99196492; called by muse, mutect2
- DNAH7 | c.10246G>C p.D3416H | Missense Mutation (SNP) | VAF 8/183 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100415707, COSV56775529; called by muse, mutect2
- ELF1 | c.917C>T p.S306F | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV99523127; called by muse, mutect2
- ENPP6 | c.1253C>T p.A418V | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99698879; called by muse, mutect2
- EXOC2 | c.2161C>G p.L721V | Missense Mutation (SNP) | VAF 13/180 reads (7%) | SIFT tolerated (0.9); PolyPhen benign (0.012); catalogued as COSV100033739; called by muse, mutect2
- FANCD2 | c.1632G>C p.Q544H | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.652); catalogued as COSV99811584; called by muse, mutect2
- FANCI | c.2890-1G>A p.X964_splice (on ENST00000310775 / NM_001376911.1; = p.X904_splice on NM_018193.3) | Splice Site (SNP) | VAF 8/134 reads (6%) | catalogued as COSV100168120; called by muse, mutect2
- FGF23 | c.597G>A p.M199I | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV52975948; called by muse, mutect2
- FLG | c.9725C>T p.S3242F | Missense Mutation (SNP) | VAF 26/486 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100911666; called by muse, mutect2
- FOXP1 | c.1298G>A p.G433E | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV100561838; called by muse, mutect2
- FRMD5 | c.786G>C p.Q262H | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV101296602, COSV68720387; called by muse, mutect2, varscan2
- FRYL | c.8746G>C p.E2916Q | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.306); catalogued as COSV51946180, COSV99977155; called by muse, mutect2
- GABRB3 | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100165301; called by muse, mutect2
- GALNT15 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.075); catalogued as COSV60216645; called by muse, mutect2
- GAPDH | c.851C>G p.S284C | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs1429726582, COSV57522273, COSV99975572; called by muse, mutect2
- GCLC | c.1252C>T p.P418S (on ENST00000643939; = p.P416S on NM_001498.4) | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.668); catalogued as rs1435057476, COSV99988693; called by muse, mutect2
- GCNT4 | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as COSV100466517; called by muse, mutect2
- GFAP | c.1219C>G p.L407V | Missense Mutation (SNP) | VAF 11/216 reads (5%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.807); catalogued as COSV99493365; called by muse, mutect2
- GLS2 | c.1556C>T p.S519L | Missense Mutation (SNP) | VAF 31/201 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as rs756058907, COSV100358380, COSV57665325; called by muse, mutect2, varscan2
- GPC5 | c.1148G>A p.R383K | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as COSV100994393; called by muse, mutect2
- GPR37 | c.1133C>T p.S378L | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV100390900; called by muse, mutect2
- GTF2H5 | c.106C>G p.Q36E | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV101659565, COSV101659572; called by muse, mutect2
- HMCN1 | c.4708G>A p.E1570K | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV99629767; called by muse, mutect2
- HNRNPA1 | c.1112G>C p.R371T (on ENST00000340913 / NM_031157.4; = p.R319T on NM_002136.4) | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.143); catalogued as COSV52935862; called by muse, mutect2
- IL17A | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.825); catalogued as COSV100391544; called by muse, mutect2
- IMP4 | c.214G>C p.D72H | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99383761; called by muse, mutect2, varscan2
- INTS6L | c.1456G>C p.E486Q | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.772); catalogued as COSV100878141; called by muse, mutect2
- IRX6 | c.5C>G p.S2C | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV51862188, COSV99306540; called by muse, mutect2
- JAK1 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.985); catalogued as COSV100691926, COSV61095176; called by muse, mutect2
- KIAA1109 | c.14236G>A p.E4746K | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV99165477; called by muse, mutect2
- KLHL11 | c.1759G>A p.E587K | Missense Mutation (SNP) | VAF 9/171 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as COSV100044365; called by muse, mutect2
- KMT2A | c.2758G>C p.D920H | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV100629057, COSV63282117; called by muse, mutect2
- KMT2C | c.12208C>T p.P4070S | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100072866; called by muse, mutect2, varscan2
- KNTC1 | c.3494C>T p.S1165F | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.036); catalogued as COSV100338424; called by muse, mutect2
- LOXL2 | c.1975G>C p.E659Q | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101207926; called by muse, mutect2
- MAGI3 | c.2515G>C p.E839Q | Missense Mutation (SNP) | VAF 22/379 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.156); catalogued as COSV100289456; called by muse, mutect2
- MAP1A | c.2089G>A p.E697K | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.991); catalogued as COSV100288781; called by muse, mutect2
- MAP3K10 | c.1441G>C p.E481Q | Missense Mutation (SNP) | VAF 11/173 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99454252; called by muse, mutect2
- MAPKBP1 | c.2851G>A p.E951K (on ENST00000456763 / NM_001128608.2; = p.E945K on NM_014994.3) | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.16); catalogued as COSV99529678; called by muse, mutect2
- MASTL | c.1615G>A p.D539N | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.339); catalogued as COSV100668900; called by muse, mutect2
- MMP27 | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.05); catalogued as COSV99498475; called by muse, mutect2
- MMP8 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99368501; called by muse, mutect2
- MPP1 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 8/169 reads (5%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV101053702; called by muse, mutect2
- MSI2 | c.298C>T p.R100* | Nonsense Mutation (SNP) | VAF 12/166 reads (7%) | catalogued as COSV52367561; called by muse, mutect2
- MTBP | c.1171G>A p.D391N | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as COSV100012228; called by muse, mutect2
- MTMR7 | c.1009C>T p.H337Y | Missense Mutation (SNP) | VAF 36/484 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99472502; called by muse, mutect2
- MUC16 | c.39153C>G p.F13051L | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.193); catalogued as COSV101200188; called by muse, mutect2
- MUC3A | c.7382C>T p.S2461L | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT deleterious, low confidence (0.04); catalogued as rs1374849774, COSV100114758; called by muse, mutect2
- MYH2 | c.4681G>A p.E1561K | Missense Mutation (SNP) | VAF 20/274 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs748063533, COSV99820365; called by muse, mutect2
- NABP2 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV57212925; called by muse, mutect2
- NFATC2 | c.631C>G p.H211D | Missense Mutation (SNP) | VAF 12/197 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.113); catalogued as COSV101044232; called by muse, mutect2
- NIPBL | c.5857C>T p.Q1953* | Nonsense Mutation (SNP) | VAF 21/140 reads (15%) | catalogued as COSV99240995; called by muse, mutect2, varscan2
- NMD3 | c.985C>G p.R329G | Missense Mutation (SNP) | VAF 15/176 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100664722, COSV63618066; called by muse, mutect2
- NOTCH4 | c.1546G>C p.E516Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100900736; called by muse, mutect2, varscan2
- NPTX1 | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV100151061; called by muse, mutect2
- NUDT17 | c.830G>C p.R277T | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV57907702; called by muse, mutect2
- NUP133 | c.779C>G p.S260C | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54569664, COSV99773033; called by muse, mutect2
- NXF5 | n.1440G>C | Splice Region (SNP) | VAF 18/166 reads (11%) | catalogued as COSV99534440; called by muse, mutect2, varscan2
- OR1N2 | c.800C>G p.S267* | Nonsense Mutation (SNP) | VAF 11/181 reads (6%) | catalogued as COSV101031412, COSV65461190; called by muse, mutect2
- OR4C12 | c.454C>T p.L152F | Missense Mutation (SNP) | VAF 12/284 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.25); catalogued as COSV58859765, COSV58860518; called by muse, mutect2
- OR4C6 | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 32/234 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.67); catalogued as COSV58602302; called by muse, mutect2, varscan2
- OR8H3 | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 20/460 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100539018, COSV57908220; called by muse, mutect2
- OS9 | c.1839G>T p.E613D | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99223486; called by mutect2, varscan2
- PAMR1 | c.1395G>C p.Q465H (on ENST00000619888 / NM_001001991.3; = p.Q482H on NM_015430.4) | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.202); catalogued as COSV99552760; called by muse, mutect2
- PCDHA3 | c.43C>G p.L15V | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV100973934, COSV65370026; called by muse, mutect2
- PCDHB15 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.025); catalogued as COSV50917588; called by muse, mutect2
- PDE10A | c.1589C>T p.A530V | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as rs749581970, COSV63090458; called by muse, mutect2
- PEG3 | c.2194C>G p.Q732E | Missense Mutation (SNP) | VAF 8/185 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV99689307; called by muse, mutect2
- PEX5 | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.786); catalogued as COSV99871033; called by muse, mutect2, varscan2
- PFKP | c.1132G>C p.D378H | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.418); catalogued as COSV101127320; called by muse, mutect2
- PLEKHG2 | c.1555T>G p.S519A | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.017); catalogued as COSV99217602; called by muse, mutect2, varscan2
- POLR2J | c.21C>G p.F7L | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.225); catalogued as COSV99484486; called by muse, mutect2
- PPARGC1A | c.202C>T p.Q68* | Nonsense Mutation (SNP) | VAF 7/118 reads (6%) | catalogued as COSV99337395, COSV99338063; called by muse, mutect2
- PPL | c.2565G>C p.Q855H | Missense Mutation (SNP) | VAF 19/333 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99278147; called by muse, mutect2
- PRRG1 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV101069009; called by muse, mutect2, varscan2
- PTPRB | c.1325G>T p.R442I | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99717764; called by muse, mutect2
- RAB11FIP1 | c.1552G>C p.E518Q | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.359); catalogued as COSV99770150; called by muse, mutect2
- RAB3GAP1 | c.2042C>T p.S681L | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99921262; called by muse, mutect2
- RBAK | c.1409C>T p.S470L | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV62332421; called by muse, mutect2
- REV3L | c.5438C>T p.S1813L | Missense Mutation (SNP) | VAF 12/227 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.1); catalogued as COSV100725309; called by muse, mutect2
- RIC1 | c.2423G>A p.R808K | Missense Mutation (SNP) | VAF 15/209 reads (7%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs1168748171, COSV99317471; called by muse, mutect2
- RNF165 | c.454C>G p.Q152E | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.236); catalogued as COSV99491771; called by muse, mutect2
- SAMD14 | c.500-1G>A p.X167_splice | Splice Site (SNP) | VAF 3/45 reads (7%) | catalogued as COSV99557467; called by muse, mutect2
- SAYSD1 | c.429G>C p.E143D | Missense Mutation (SNP) | VAF 28/204 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.157); catalogued as COSV100010016, COSV100010192; called by muse, mutect2, varscan2
- SEC31A | c.1450G>A p.D484N | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.171); catalogued as COSV100021964; called by muse, mutect2
- SENP5 | c.1979C>G p.S660* | Nonsense Mutation (SNP) | VAF 7/180 reads (4%) | catalogued as COSV100052075; called by muse, mutect2
- SERPINA6 | c.131T>C p.V44A | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as rs537835110, COSV100448322; called by muse, mutect2, varscan2
- SF3B1 | c.3478G>A p.E1160K | Missense Mutation (SNP) | VAF 13/181 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as COSV59224550; called by muse, mutect2
- SIRT5 | c.84G>C p.Q28H | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.081); catalogued as rs1341934892, COSV100702860; called by muse, mutect2
- SLC11A2 | c.259C>G p.P87A (on ENST00000394904 / NM_001379455.1; = p.P58A on NM_000617.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV100014799; called by muse, mutect2
- SLC15A2 | c.1270G>A p.D424N | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs1218053874, COSV99815573; called by muse, mutect2
- SLC39A10 | c.1353G>A p.M451I | Missense Mutation (SNP) | VAF 17/206 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as COSV100660638; called by muse, mutect2
- SLC4A4 | c.535C>T p.L179F (on ENST00000264485 / NM_001098484.3; = p.L135F on NM_003759.4) | Missense Mutation (SNP) | VAF 23/192 reads (12%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.995); catalogued as COSV99140449; called by muse, mutect2, varscan2
- SMAD2 | c.1363C>T p.Q455* | Nonsense Mutation (SNP) | VAF 9/85 reads (11%) | catalogued as COSV51011397; called by muse, mutect2
- SPATA22 | c.877C>G p.L293V | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); catalogued as COSV99279290; called by muse, mutect2
- SPTAN1 | c.2692G>A p.D898N | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as rs1173940623, COSV100823677; called by muse, mutect2, varscan2
- STK17B | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 9/149 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99826159; called by muse, mutect2
- STXBP5L | c.1726C>T p.P576S | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV56501250; called by muse, mutect2
- TANC1 | c.4095G>C p.L1365F | Missense Mutation (SNP) | VAF 19/308 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99714227; called by muse, mutect2
- TCHH | c.4856G>C p.R1619T | Missense Mutation (SNP) | VAF 15/192 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as COSV100915175, COSV64275885; called by muse, mutect2
- TG | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 9/243 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.449); catalogued as COSV55075236, COSV99601422; called by muse, mutect2
- TGM4 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.179); catalogued as COSV99942099, COSV99942398; called by muse, mutect2
- TLK1 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV62632301; called by muse, mutect2
- TM4SF19 | c.136C>G p.L46V | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99879382; called by muse, mutect2
- TOP2A | c.67G>C p.D23H | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.401); catalogued as COSV101396236; called by muse, mutect2
- TRIM15 | c.760G>C p.E254Q | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV100938839; called by muse, mutect2
- TRIM27 | c.1066C>A p.L356M | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.935); catalogued as COSV101019354; called by muse, mutect2, varscan2
- TRPM7 | c.3229C>T p.Q1077* | Nonsense Mutation (SNP) | VAF 9/145 reads (6%) | catalogued as COSV100539952; called by muse, mutect2
- TTK | c.407G>C p.R136T | Missense Mutation (SNP) | VAF 11/252 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV100036368; called by muse, mutect2
- TTN | c.95089G>A p.E31697K (on ENST00000591111; = p.E24273K on NM_003319.4) | Missense Mutation (SNP) | VAF 8/67 reads (12%) | PolyPhen benign (0.038); catalogued as COSV100617671; called by muse, mutect2, varscan2
- TTN | c.87360G>C p.K29120N (on ENST00000591111; = p.K21696N on NM_003319.4) | Missense Mutation (SNP) | VAF 9/129 reads (7%) | PolyPhen probably damaging (0.997); catalogued as COSV100617674, COSV60470117; called by muse, mutect2
- TTN | c.62746G>A p.D20916N (on ENST00000591111; = p.D13492N on NM_003319.4) | Missense Mutation (SNP) | VAF 5/67 reads (7%) | PolyPhen possibly damaging (0.856); catalogued as COSV100617675; called by muse, mutect2
- TTN | c.45949G>C p.D15317H (on ENST00000591111; = p.D7893H on NM_003319.4) | Missense Mutation (SNP) | VAF 5/45 reads (11%) | PolyPhen possibly damaging (0.747); catalogued as COSV100617677, COSV100620430; called by muse, mutect2, varscan2
- UBA2 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.85); catalogued as COSV99875580; called by muse, mutect2
- UBR2 | c.2681C>T p.S894L | Missense Mutation (SNP) | VAF 19/292 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV100867463; called by muse, mutect2
- UGGT2 | c.292C>G p.L98V | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); catalogued as COSV100942487, COSV100942582; called by muse, mutect2
- UNC45A | c.96C>G p.F32L | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as COSV100376586; called by muse, mutect2
- VRK2 | c.1283C>G p.S428* | Nonsense Mutation (SNP) | VAF 7/93 reads (8%) | catalogued as COSV99287659; called by muse, mutect2
- WDR45 | c.409G>C p.E137Q (on ENST00000376372 / NM_001029896.2; = p.E138Q on NM_007075.3) | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as COSV100540287; called by muse, mutect2
- WDR5B | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 19/352 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100413121; called by muse, mutect2
- YTHDC2 | c.1082G>A p.G361E | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.368); catalogued as rs922377763, COSV99363477; called by muse, mutect2
- ZBTB6 | c.934C>T p.H312Y | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as COSV101022021; called by muse, mutect2
- ZNF215 | c.874G>C p.E292Q | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV99549697; called by muse, mutect2
- ZNF236 | c.3331G>A p.E1111K | Missense Mutation (SNP) | VAF 12/195 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0.202); catalogued as COSV99470545; called by muse, mutect2
- ZNF420 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.354); catalogued as COSV100421397; called by muse, mutect2
- ZSCAN4 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as COSV100552521, COSV59000663; called by muse, mutect2
- EIF2AK3 | c.419C>T p.S140F | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- GPR179 | c.3035G>A p.G1012D (on ENST00000621958; = p.G1011D on NM_001004334.4) | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- HSPH1 | c.880G>C p.D294H | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KHDC4 | c.1599dup p.E534Rfs*4 | Frame Shift Ins (INS) | VAF 52/462 reads (11%) | called by mutect2, pindel, varscan2
- SEMA5A | c.2827G>C p.D943H | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.022); called by muse, mutect2
- SERPINE3 | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SNRPN | c.660G>A p.M220I | Missense Mutation (SNP) | VAF 9/203 reads (4%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2
- STRADB | c.980del p.S327Mfs*46 | Frame Shift Del (DEL) | VAF 10/80 reads (13%) | called by mutect2, varscan2
- TENT2 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 13/428 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TMEM108 | c.1072G>A p.G358R | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.301); called by muse, mutect2
- UACA | c.3914G>C p.R1305T | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2
- ZBTB40 | c.1910C>T p.S637L | Missense Mutation (SNP) | VAF 6/125 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- ZNF750 | c.2032_2043delinsTTAGGCAGT p.A678_D681delinsLGS | In Frame Del (DEL) | VAF 25/127 reads (20%) | called by pindel, varscan2*
- ABCB4 | c.1251G>A p.L417= | Silent (SNP) | VAF 9/165 reads (5%) | catalogued as COSV99710627; called by muse, mutect2
- AC109583.1 | c.219C>G p.L73= | Silent (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- ADNP2 | c.2337C>T p.F779= | Silent (SNP) | VAF 12/177 reads (7%) | catalogued as COSV100080961; called by muse, mutect2
- ANKRD12 | c.1218C>T p.F406= | Silent (SNP) | VAF 8/149 reads (5%) | catalogued as COSV100041507; called by muse, mutect2
- ARHGEF17 | c.4224G>A p.L1408= | Silent (SNP) | VAF 15/169 reads (9%) | catalogued as COSV99735870; called by muse, mutect2
- ARPC1A | c.1041C>T p.G347= | Silent (SNP) | VAF 13/109 reads (12%) | catalogued as COSV99501240; called by muse, mutect2, varscan2
- ATF1 | c.276C>T p.V92= | Silent (SNP) | VAF 11/138 reads (8%) | catalogued as COSV100016135; called by muse, mutect2
- ATF6B | c.1608G>A p.E536= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV100916835; called by mutect2, varscan2
- ATN1 | c.1054C>T p.L352= | Silent (SNP) | VAF 16/190 reads (8%) | catalogued as rs1555143635, COSV100755823, COSV63110550; called by muse, mutect2
- ATP8A2 | c.1083C>T p.Y361= | Silent (SNP) | VAF 9/196 reads (5%) | catalogued as COSV99682431; called by muse, mutect2
- BCO2 | c.717G>T p.G239= | Silent (SNP) | VAF 9/174 reads (5%) | catalogued as COSV100730382; called by muse, mutect2
- CCDC150 | c.909C>G p.L303= | Silent (SNP) | VAF 10/158 reads (6%) | catalogued as COSV99777064; called by muse, mutect2
- CCDC191 | c.2448G>A p.Q816= | Silent (SNP) | VAF 16/252 reads (6%) | catalogued as COSV99878355; called by muse, mutect2
- CDC42BPG | c.1935G>A p.L645= | Silent (SNP) | VAF 32/470 reads (7%) | catalogued as rs950710427, COSV100712101; called by muse, mutect2
- CDC42BPG | c.1884G>C p.P628= | Silent (SNP) | VAF 20/256 reads (8%) | catalogued as COSV100712102; called by muse, mutect2
- CEBPA | c.936G>A p.Q312= | Silent (SNP) | VAF 6/104 reads (6%) | catalogued as COSV100204618; called by muse, mutect2
- CPS1 | c.42G>A p.L14= | Silent (SNP) | VAF 9/155 reads (6%) | catalogued as COSV99243235; called by muse, mutect2
- DAGLA | c.1023C>T p.I341= | Silent (SNP) | VAF 27/267 reads (10%) | catalogued as rs771890239, COSV57194452; called by muse, mutect2, varscan2
- DEPDC1 | c.1437C>T p.F479= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV100920371; called by muse, mutect2
- DFFA | c.573C>T p.L191= | Silent (SNP) | VAF 10/191 reads (5%) | catalogued as COSV100986660; called by muse, mutect2
- DIP2B | c.3180C>T p.I1060= | Silent (SNP) | VAF 19/169 reads (11%) | catalogued as rs747998083, COSV56582858; called by muse, mutect2, varscan2
- DLEC1 | c.2292C>T p.I764= | Silent (SNP) | VAF 16/248 reads (6%) | catalogued as COSV100342631; called by muse, mutect2
- DLGAP1 | c.81C>T p.S27= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as rs200480488, COSV59835059; called by muse, mutect2
- DNAH2 | c.2718C>T p.V906= | Silent (SNP) | VAF 14/300 reads (5%) | catalogued as rs1326348584, COSV66723442; called by muse, mutect2
- EIF2AK3 | c.1503C>T p.L501= | Silent (SNP) | VAF 15/182 reads (8%) | catalogued as rs761573254, COSV57551426; called by muse, mutect2
- ENPP3 | c.2535C>T p.L845= | Silent (SNP) | VAF 12/191 reads (6%) | catalogued as COSV100717472; called by muse, mutect2
- EPB41L5 | c.1345C>T p.L449= | Silent (SNP) | VAF 8/222 reads (4%) | catalogued as COSV99758832; called by muse, mutect2
- EPG5 | c.5040C>T p.V1680= | Silent (SNP) | VAF 12/170 reads (7%) | catalogued as COSV99957473; called by muse, mutect2
- FAM160B1 | c.330C>T p.F110= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV100985148, COSV100985164; called by muse, mutect2
- FCGR2A | c.390C>T p.H130= (on ENST00000271450 / NM_001136219.3; = p.H129= on NM_021642.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/155 reads (7%) | catalogued as COSV99615422; called by muse, mutect2
- FRYL | c.2602C>T p.L868= | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as COSV99977160; called by muse, mutect2
- GALC | c.1140C>T p.L380= | Silent (SNP) | VAF 6/123 reads (5%) | called by muse, mutect2
- GBE1 | c.720C>T p.I240= | Silent (SNP) | VAF 12/150 reads (8%) | catalogued as COSV101450177; called by muse, mutect2
- GMPS | c.657G>A p.V219= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as rs1180370264, COSV99903216; called by muse, mutect2, varscan2
- HAVCR2 | c.264C>T p.F88= | Silent (SNP) | VAF 13/154 reads (8%) | catalogued as COSV57152959; called by muse, mutect2
- HMGCL | c.930G>A p.L310= | Silent (SNP) | VAF 7/152 reads (5%) | catalogued as COSV99353971; called by muse, mutect2
- HOOK2 | c.2131C>T p.L711= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as rs1481707486, COSV99244464; called by muse, mutect2
- HOXB1 | c.672C>T p.F224= | Silent (SNP) | VAF 11/229 reads (5%) | catalogued as COSV99495553; called by muse, mutect2
- IL17RA | c.1764G>A p.E588= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100083210; called by muse, mutect2
- IQGAP3 | c.3987C>T p.I1329= | Silent (SNP) | VAF 18/177 reads (10%) | catalogued as rs139057334; called by muse, mutect2, varscan2
- IQUB | c.81C>T p.V27= | Silent (SNP) | VAF 8/142 reads (6%) | catalogued as COSV100227166; called by muse, mutect2
- KATNB1 | c.840C>T p.I280= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as COSV101109956; called by muse, mutect2
- KIAA2026 | c.3774G>A p.Q1258= | Silent (SNP) | VAF 9/102 reads (9%) | catalogued as COSV101199088; called by muse, mutect2
- KRT18 | c.1284G>C p.L428= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV101184041, COSV101184043; called by muse, mutect2
- LMBR1L | c.375C>T p.I125= | Silent (SNP) | VAF 8/130 reads (6%) | catalogued as COSV99918825; called by muse, mutect2
- MAGI2 | c.714G>A p.E238= | Silent (SNP) | VAF 31/330 reads (9%) | catalogued as rs1350468426, COSV100834914; called by muse, mutect2
- MAP3K3 | c.1119C>T p.F373= | Silent (SNP) | VAF 11/133 reads (8%) | catalogued as rs201713792, COSV100675557; called by muse, mutect2
- MED16 | c.1179C>T p.I393= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs200919426; called by muse, mutect2, varscan2
- MLH3 | c.3144C>T p.F1048= | Silent (SNP) | VAF 12/150 reads (8%) | catalogued as rs753531927, COSV53155158; called by muse, mutect2
- NEK7 | c.303C>T p.F101= | Silent (SNP) | VAF 14/220 reads (6%) | catalogued as COSV100954724, COSV66314219; called by muse, mutect2
- NLN | c.1020G>A p.L340= | Silent (SNP) | VAF 13/169 reads (8%) | catalogued as COSV101114336; called by muse, mutect2
- NLRP12 | c.12C>T p.T4= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as rs750234197, COSV100145167, COSV60751093; called by mutect2, varscan2
- NPR3 | c.789C>T p.S263= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs969206323, COSV99423207; called by muse, mutect2, varscan2
- NUDCD3 | c.198C>T p.F66= | Silent (SNP) | VAF 8/95 reads (8%) | catalogued as COSV100819370; called by muse, mutect2
- OLFML2A | c.321G>A p.E107= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV100053743; called by muse, mutect2
- OR5A2 | c.408C>T p.L136= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV100119769; called by muse, mutect2
- PCDHB13 | c.1003C>T p.L335= | Silent (SNP) | VAF 26/308 reads (8%) | catalogued as COSV99507391; called by muse, mutect2
- PFKM | c.1417C>T p.L473= | Silent (SNP) | VAF 14/229 reads (6%) | catalogued as COSV100402533; called by muse, mutect2
- PHLDB1 | c.3465G>A p.L1155= | Silent (SNP) | VAF 10/172 reads (6%) | catalogued as COSV100616597; called by muse, mutect2
- PLK4 | c.348C>T p.F116= | Silent (SNP) | VAF 15/211 reads (7%) | catalogued as rs1386714540, COSV99584701; called by muse, mutect2
- PROX2 | c.1521C>T p.V507= (on ENST00000556489 / NM_001243007.1; = p.V280= on NM_001080408.2) | Silent (SNP) | VAF 8/165 reads (5%) | catalogued as rs987612225, COSV101507813; called by muse, mutect2
- PTER | c.639C>T p.I213= | Silent (SNP) | VAF 7/112 reads (6%) | called by muse, mutect2
- PYCR2 | c.757C>T p.L253= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV100661526; called by muse, mutect2, varscan2
- RHOBTB1 | c.1134C>T p.F378= | Silent (SNP) | VAF 7/132 reads (5%) | catalogued as COSV100558523, COSV61958779; called by muse, mutect2
- RTL3 | c.36G>A p.L12= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as COSV100329867; called by muse, mutect2
- SCN1A | c.2646C>T p.I882= (on ENST00000303395 / NM_001202435.3; = p.I871= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/134 reads (4%) | catalogued as COSV100320819; called by muse, mutect2
- SCN2A | c.3144A>G p.K1048= | Silent (SNP) | VAF 7/91 reads (8%) | catalogued as COSV99332114; called by muse, mutect2
- SCRG1 | c.276G>A p.V92= | Silent (SNP) | VAF 7/126 reads (6%) | catalogued as COSV99633520; called by muse, mutect2
- SERPINA5 | c.1116C>T p.F372= | Silent (SNP) | VAF 22/453 reads (5%) | catalogued as COSV100291682; called by muse, mutect2
- SHOC1 | c.162C>T p.V54= | Silent (SNP) | VAF 9/122 reads (7%) | catalogued as COSV100597725; called by muse, mutect2
- SLCO3A1 | c.825C>T p.L275= | Silent (SNP) | VAF 8/145 reads (6%) | catalogued as COSV100575544; called by muse, mutect2
- SMAD3 | c.945C>G p.V315= | Silent (SNP) | VAF 7/94 reads (7%) | catalogued as rs1363502533, COSV100529121; called by muse, mutect2
- SPR | c.333C>T p.F111= | Silent (SNP) | VAF 8/142 reads (6%) | catalogued as COSV99318064; called by muse, mutect2
- SPTLC2 | c.771G>C p.L257= | Silent (SNP) | VAF 7/93 reads (8%) | catalogued as COSV99377513; called by muse, mutect2
- TCFL5 | c.198G>A p.E66= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV99415931; called by mutect2, varscan2
- TENT5D | c.678G>A p.R226= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as COSV100382791; called by muse, mutect2, varscan2
- TLR3 | c.2091A>G p.K697= | Silent (SNP) | VAF 46/394 reads (12%) | catalogued as COSV99711052; called by muse, mutect2, varscan2
- TRPC4AP | c.819G>A p.Q273= | Silent (SNP) | VAF 15/167 reads (9%) | catalogued as COSV99328504; called by muse, mutect2
- TRRAP | c.2850G>A p.L950= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV100722597; called by muse, mutect2, varscan2
- UBE3C | c.2748G>C p.R916= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV100779993, COSV61952320; called by muse, mutect2, varscan2
- ZBTB20 | c.465T>A p.I155= (on ENST00000474710 / NM_001164342.2; = p.I82= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 13/91 reads (14%) | catalogued as COSV100614101; called by muse, mutect2, varscan2
- ZFC3H1 | c.48G>A p.P16= | Silent (SNP) | VAF 12/232 reads (5%) | catalogued as COSV100350502; called by muse, mutect2
- ZFYVE1 | c.2232C>T p.F744= | Silent (SNP) | VAF 12/113 reads (11%) | catalogued as COSV100606829; called by muse, mutect2, varscan2
- ZNF214 | c.882G>A p.Q294= | Silent (SNP) | VAF 18/253 reads (7%) | catalogued as COSV99547460; called by muse, mutect2
- ZNF468 | c.858C>T p.L286= | Silent (SNP) | VAF 14/235 reads (6%) | catalogued as COSV54696618, COSV99700630; called by muse, mutect2
- ZNFX1 | c.1599G>A p.Q533= | Silent (SNP) | VAF 10/126 reads (8%) | catalogued as rs749619371, COSV100870895; called by muse, mutect2
- DCHS2 | n.1791C>T | RNA (SNP) | VAF 10/91 reads (11%) | catalogued as rs72966165, COSV100252154; called by muse, mutect2, varscan2
- POLQ | chr3:121546611 G>A | 5'Flank (SNP) | VAF 8/162 reads (5%) | called by muse, mutect2
- TTN | c.10361-5176G>A | Intron (SNP) | VAF 13/154 reads (8%) | catalogued as rs745711328, COSV60105992; called by muse, mutect2
